Gene-level copy-number profile of tumor specimen TCGA-BA-5559-01A from TCGA case TCGA-BA-5559, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: G3; Age at diagnosis: 72.0 years (26,286 days).
Specimen TCGA-BA-5559-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.6aaad7bb-5f59-40b3-bdc9-b33fa0764358.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-5559-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0b8f601d-2894-4a9b-8b43-a3eba0374b2a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2,852; copy number 2: 41,615; copy number 3: 12,001; copy number 4: 1,867; copy number 5: 1,484.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BA-5559-01A-01D-1510-01): tumor purity 0.62, ploidy 2.37, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:1,018,757–1,019,704, 1 gene: AC129915.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,484 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:143,855,739–160,485,773, 272 genes, copy number 5 (broad region; genes not listed).
- chr3:160,514,907–160,515,236, 1 gene, copy number 5: SCARNA7.
- chr3:185,643,130–185,825,042, 1 gene, copy number 5 (within-gene range 4–5): IGF2BP2.
- chr3:185,767,847–187,746,028, 57 genes, copy number 5: MIR548AQ, TRA2B, NMRAL2P, ETV5, Metazoa_SRP, ETV5-AS1, DGKG, LINC02020, LINC02052, LINC02051, CRYGS, TBCCD1, DNAJB11, AC068631.1, AC068631.2, AC068631.3, AHSG, Metazoa_SRP, FETUB, HRG, AC109780.1, AC109780.2, KNG1, PSMD10P2, RNU6-1105P, GPS2P2, AC112907.3, EIF4A2, SNORD2, SNORA63B, MIR1248, SNORA81, SNORA63, SNORA4, RFC4, AC112907.1, LINC02043, AC112907.2, ADIPOQ, ADIPOQ-AS1, RPS20P14, AC007690.1, ST6GAL1, RPL39L, AC007920.1, RTP1, MASP1, AC007920.2, RTP4, AC068299.2, AC068299.1, LINC02041, SST, RTP2, AC072022.1, BCL6, AC072022.2.
- chr12:66,767–42,996,486, 924 genes, copy number 5 (broad region; genes not listed).
- chr20:25,611,153–35,621,094, 229 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,852. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
